Surgical pathology report (de-identified scan), TCGA case TCGA-K1-A42X, project TCGA-SARC (Sarcoma), tissue source site University of Pittsburgh, specimen TCGA-K1-A42X-01A (Primary Tumor).

FINAL DIAGNOSIS:

UTERUS, WITH BOTH ADNEXA, 320 GRAMS, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. MODERATELY DIFFERENTIATED LEIOMYOSARCOMA 7.0 CM IN DIAMETER WITH FOCAL HEMORRHAGE, INTRAMURAL, WITH WELL DIMARCATED MARGINS AND NO VASCULAR INVASION NOTED.
- B. CHRONIC CERVICITIS AND NABOTHIAN CYSTS.
- C. ENDOCERVICAL POLYP.
- D. ENDOMETRIUM WITH PROLIFERATIVE PATTERN, CYSTIC CHANGES AND FOCAL SIMPLE AND COMPLEX HYPERPLASIA WITH TUBALA METAPLASIA
- E. ADENOMYOSIS.
- F. SMALL INTRAMURAL LEIOMYOMA
- G. SURGICAL LINES OF RESECTION ARE FREE OF TUMOR.
- H. BILATERAL OVARIES WITH MULTIFOCAL DECIDUAL REACTION OF THE STROMA, MULTIPLE SIMPLE CYST AND ENDOMETRIOSIS.
- I. FALLOPIAN TUBES WITH FIBROSIS.

ICD-0-3

Leiomyosarcoma, NOS
889013

Site: Uterus, NOS
C55.9

90 12/21/12

COMMENT:

This tumor is morphologically and architecturally consistent with a leiomyosarcoma. The borders of the tumor are well circumscribed. Few tumor nodules are noted at the periphery of the main lesion, they may represent finger-like projections of the tumor rather than separate tumor nodules. The tumor cells are atypical and the mitotic count is on average 12 mitosis/10HPF after counting 70 fields. Immunostains (smooth muscle actin interpreted as positive and CD 10 interpreted as negative) have been performed and they favor the diagnosis of leiomyosarcoma.

Smooth Muscle Actin - Positive

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

- A. Epithelial neoplasia: 2 1. Yes 2. No
- A1. Endometrial Carcinoma: # 1. Yes 2. No
- A2. Type: #
1. Endometrioid Adenocarcinoma, NOS
2. Endometrioid Adenocarcinoma, Secretory Variant
3. Endometrioid Adenocarcinoma, Ciliated Variant
4. Adenocarcinoma with squamous metaplasia (adenocanthoma)
5. Adenosquamous Carcinoma
6. Serous Adenocarcinoma
7. Clear cell adenocarcinoma
8. Mucinous adenocarcinoma
9. Squamous cell carcinoma
10. Mixed carcinoma
11. Undifferentiated carcinoma
12. Other carcinomas (including metastasis)
- B. Nonepithelial Tumor: 1 1. Yes 2. No
- B1. Type: 4
1. Low-grade stromal sarcoma
2. High-grade stromal sarcoma
3. Smooth muscle tumor of uncertain malignant potential
4. Leiomyosarcoma, NOS
5. Leiomyosarcoma variant (Epithelioid, Myxoid)
6. Mixed endometrial stromal and smooth
7. Neuroectodermal tumors
8. Lymphoma
9. Other nonepithelial tumors
- C. Mixed Epithelial-Mesodermal and Other Tumors: 2
- C1. Type: #
1. Adenosarcoma
2. Carcinosarcoma (Malignant Mixed Mesodermal Tumor)
3. Germ cell neoplasia
4. Gestational Trophoblastic Disease
5. Other tumors
- D. Grade (epithelial neoplasia): #na
1. Well Differentiated
2. Moderately Differentiated
3. Poorly Differentiated
- E. Size of neoplasm (maximum dimensions): 7 cm
- F. Depth of invasion: 0
- a. No invasion
- b. Less than 1/2 thickness of myometrium
- c. Greater than 1/2 thickness of myometrium
- d. Into serosa
- G. Structures involved:
- G1. Cervical stroma: # 1. Yes 2. No
- G2. Endocervical glands: # 1. Yes 2. No
- G3. Adnexa: # 1. Yes 2. No
- G4. Vagina: # 1. Yes 2. No
- G5. Bladder and/or Bowel mucosa: # 1. Yes 2. No
- H. Non-neoplastic or Pre-neoplastic conditions: 0
1. Endometrial polyp
2. Simple Endometrial Hyperplasia without Atypia
3. Simple Endometrial Hyperplasia with Atypia
4. Complex Endometrial Hyperplasia without Atypia
5. Complex Endometrial Hyperplasia with Atypia
6. Adenomyosis
7. Inflammatory Pseudotumor
8. Other
- I. Margins of resection:
- I1. Cervix or vaginal: 2 1. Positive 2. Negative
- I2. Parametrium: 1. Positive 2. Negative
- J. Mitotic count (sarcomas only): 12 per 10 high powered fields
- K. Angiolymphatic invasion: 2 1. Yes 2. No
- L. Regional Lymph node metastases:
- L1. Number of positive lymph nodes: #
- L2. Total number of lymph nodes examined: #
- L3. Pelvic:

Right: # positive / total #	Left: # positive / total #
-----------------------------	----------------------------
- L4. Hypogastric (Obturator): Right: # positive / total # Left: # positive / total #
- L5. Common iliac: Right: # positive / total # Left: # positive / total #
- L6. External iliac: Right: # positive / total # Left: # positive / total #
- L7. Parametrial: Right: # positive / total # Left: # positive / total #
- L8. Sacral: # / # Right: # positive / total # Left: # positive / total #
- L9. Para-aortic: Right: # positive / total # Left: # positive / total #
- M. Extracapsular spread of lymph node metastases: # 1. Yes 2. No
- N. Distant Metastases: # 1. Yes 2. No
- O. (Excludes metastases to vagina, pelvic serosa, and adnexa. Includes lymph nodes other than regional lymph nodes.)
- P. TNM Stage: T2 NX MX
- Q. FIGO Stage: #
- R. Residual tumor: # 1. Rx 2. Ro 3. R1 4. R2

Other Malignancy History		

Source: NCI Genomic Data Commons file 6a100fd4-9eef-4186-9d2e-555a7acff569 (TCGA-K1-A42X.DADAEC06-42DB-4627-8C74-E23D39B3E2DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).